Surgical pathology report (de-identified scan), TCGA case TCGA-MI-A75C, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MI-A75C-01A (Primary Tumor).

[page 1 of 2]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received

A. SEGMENT 6 WEDGE RESECTION OF LIVER-FOR FROZEN

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

Segment 6 liver mass

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

Segment 6 liver mass

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

The specimen is received fresh and consists of an 8.5 x 5.0 x 5.0 cm resection of liver. Externally, the capsule is tan-red and shiny. However, a 3.0 x 3.0 x 2.5 cm firm nodular growth is identified which is still covered by capsule. On sectioning, the growth is encapsulated and is tan-yellow to brown with area of hemorrhage and necrosis. The tumor is 2.3 cm away from the closest hepatic margin. A touch preparation slide is prepared from the mass.

Representative sections are submitted as follows: 1- closest tumor margin; 2-6- representative sections of tumor.

FROZEN SECTION DIAGNOSIS:

FsA. Segment 6, wedge resection of liver:

- HEPATOCELLULAR CARCINOMA (BY CYTOLOGY), 2.0 CM FROM CLOSEST MARGIN GROSSLY

MICROSCOPIC EXAM

FINAL DIAGNOSIS:

SEGMENT 6 OF LIVER, WEDGE RESECTION:

- SPECIMEN TYPE: LIVER, WEDGE RESECTION.
- LATERALITY: RIGHT.
- TUMOR SITE: SEGMENT 6 SUBCAPSULAR.
- TUMOR CONFIGURATION: ROUND.
- TUMOR SIZE: 3 CM IN GREATEST DIMENSION.
- HISTOLOGIC TYPE: HEPATOCELLULAR CARCINOMA.
- HISTOLOGIC GRADE: MODERATE TO POORLY DIFFERENTIATED (G2-3).
- MARGINS

LIVER WEDGE SURGICAL MARGINS: NEGATIVE.

- LYMPHATIC INVASION: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.

PATHOLOGIC STAGING (pTN):

- PRIMARY TUMOR: pT1.

ICD O-3
Carcinoma, hepatocellular NOS 8170/3
Site Liver C22.0
JW 8/13/13

[page 2 of 2]
ADDITIONAL DIAGNOSES:

- CHRONIC HEPATITIS WITH FIBROSIS, GRADE 3, STAGE 2.
- FOCAL FATTY CHANGES.

COMMENT: WAS NOTIFIED AT THE TIME OF THE SURGICAL RESECTION.
CONCURS WITH NEW MALIGNANT DIAGNOSIS. IMAGES ARE AVAILABLE

OVER 85% OF THE TUMOR IS NECROTIC.

THE UNINVOLVED LIVER HAS ZONAL FATTY CHANGES (GRADE 2) WITH FOCAL MALLORY BODIES AND INDIVIDUAL DYING CELLS. THERE IS A CHRONIC INFLAMMATORY INFILTRATE IN ALL PORTAL TRACTS WITH EXTENSION OUT OF THE LIMITING PLATE.

In the fibrosing scoring methods, this is a Knodell 2/4, Metavir 2/4 and Ishak 3/6.

signed

Source: NCI Genomic Data Commons file 1c8650c4-2ace-4cd2-8e00-77657cedc223 (TCGA-MI-A75C.D32D0307-8132-4492-9431-51C9C71DD7A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).